MMRF case MMRF_2545 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e80a5e1f-ead1-464c-8888-5171b622627e

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.5 years (23,176 days); Days to last known disease status: 676 days (1.9 years); Days to last follow up: 676 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: Serum Free Immunoglobulin Light Chain, Kappa 1351 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.923 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 5.46 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.63 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.38 mmol/L.
- Day 85: Serum Free Immunoglobulin Light Chain, Kappa 2.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.779 mg/dL; Immunoglobulin G 2.43 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.7 g/dL; Glucose 7.15 mmol/L.
- Day 180: Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Lactate Dehydrogenase 3.77 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 7.54 mmol/L.
- Day 270: Serum Free Immunoglobulin Light Chain, Kappa 2.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 7.54 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 6.3 g/dL; Glucose 4.51 mmol/L.
- Day 382: Hemoglobin 8.06 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 5.39 mmol/L.
- Day 473: Serum Free Immunoglobulin Light Chain, Kappa 6.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.23 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 0.83 ×10⁹/L; Platelets 103 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 578 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.48 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 2.03 g/L; Immunoglobulin M 0.17 g/L; Hemoglobin 8 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 116 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.15 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.11 mmol/L.
- Day 676 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Hemoglobin 7.32 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 9.3 mmol/L.

Other clinical attributes
- Day 1: Weight: 82 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2545_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2545_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
